Surgical pathology report (de-identified scan), TCGA case TCGA-61-2088, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-61-2088-01A (Primary Tumor).

FINAL DIAGNOSIS:

PART 1: OMENTAL MASS, EXCISION -

METASTATIC CARCINOMA (4 CM) WITH PSAMMOMA BODY FORMATION.

PART 2: ANTERIOR PERITONEAL TUMOR EXCISION -

FRAGMENTS OF METASTATIC CARCINOMA.

PART 3: RIGHT ADNEXA, SALPINGO-OOPHORECTOMY -

- A. HIGH GRADE SEROUS PAPILLARY CARCINOMA (7 CM).
- B. TUMOR INVOLVES THE EXTERIOR SURFACE OF THE OVARY.
- C. NO LYMPHOVASCULAR SPACE INVASION IS IDENTIFIED.
- D. RESIDUAL OVARIAN TISSUE WITH SEROUS CYST (2 CM).
- E. FALLOPIAN TUBE WITH MICROSCOPIC FOCI OF SEROSAL TUMOR.

PART 4: LEFT ADNEXA, SALPINGO-OOPHORECTOMY -

- A. HIGH GRADE SEROUS PAPILLARY CARCINOMA (8.0 CM).
- B. TUMOR INVOLVES EXTERIOR SURFACE OF OVARY.
- C. NO LYMPHOVASCULAR SPACE INVASION IS IDENTIFIED.
- D. RESIDUAL OVARIAN TISSUE WITH SEROUS CYST (6.0 CM).
- E. FALLOPIAN TUBE WITH FOCAL EPITHELIAL ATYPIA IN FIMBRIATED END; NO DEFINITIVE INVOLVEMENT BY TUMOR.

PART 5: ANTERIOR CUL-DE-SAC TUMOR, EXCISION -

FRAGMENTS OF METASTATIC CARCINOMA.

PART 6: UTERUS AND CERVIX, TOTAL ABDOMINAL HYSTERECTOMY (128.0 GRAMS) -

- A. SEROSAL ADHESIONS WITH MICROSCOPIC DEPOSITS OF METASTATIC CARCINOMA.
- B. CERVIX WITH FOCAL MICROGLANDULAR HYPERPLASIA.
- C. ENDOMETRIUM WITH FOCAL COMPLEX HYPERPLASIA WITHOUT ATYPIA.

PART 7: LEFT PELVIC LYMPH NODE, BIOPSY -

ONE LYMPH NODE, NEGATIVE FOR NEOPLASM (0/1).

PART 8: DIAPHRAGM TUMOR, EXCISION -

METASTATIC CARCINOMA.

PART 9: FALCIFORM LIGAMENT, EXCISION -

METASTATIC CARCINOMA.

PART 10: OMENTUM, OMENTECTOMY -

- A. OMENTUM WITH MULTIPLE FOCI OF TUMOR MEASURING UP TO APPROXIMATELY 2.0 CM.
- B. NO DEFINITE LYMPHOVASCULAR INVASION IS IDENTIFIED.

PART 11: APPENDIX, APPENDECTOMY -

APPENDIX WITH FIBRO-INTIMAL ABLATION AND SEROSAL ADHESIONS, NEGATIVE FOR TUMOR.

SYNOPTIC - PRIMARY OVARIAN TUMORS INCLUDING BORDERLINE TUMORS

TUMOR LOCATION:	Bilateral
PROCEDURE:	TAH with salpingo-oophorectomy
TUMOR SIZE:	Maximum dimension: 8.0 cm
TUMOR TYPE:	Papillary serous carcinoma
HISTOLOGIC GRADE (serous tumors):	High grade
VASCULAR INVASION:	No
TUMOR CAPSULE:	Ruptured
MALIGNANT CELLS IN ASCITES OR PERITONEAL WASHING:	Yes
LYMPH NODES EXAMINED:	Total number of lymph nodes examined: 1
LYMPH NODES POSITIVE:	Number of positive lymph nodes, Right: 0 Number of positive lymph nodes, Left: 0

T STAGE, PATHOLOGIC:

T STAGE, PATHOLOGIC** continued on next page

T STAGE, PATHOLOGIC** continued

pT3c

N STAGE, PATHOLOGIC:

pN0

M STAGE, PATHOLOGIC:

pMX

FIGO STAGE:

IIIC

Source: NCI Genomic Data Commons file 54db179d-46a9-4568-aa17-0debbecdc8c8 (TCGA-61-2088.62624308-45B6-46F3-85A0-5A4639B44BF3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).